TCGA case TCGA-N7-A4Y5 — Uterine Carcinosarcoma (TCGA-UCS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Corpus uteri; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/245e4254-dbc1-45bd-b5df-504d8c3822de

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 87 years; Vital status: Dead; Days to death: 8 days.

Diagnoses (1)
1. Mullerian mixed tumor: ICD-O-3 morphology code: 8950/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 87.8 years (32,058 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIB; FIGO staging edition year: 1988; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 100.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes tested: 0.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 8 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 42 kg; Height: 140 cm; BMI: 21.4.
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 0; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-N7-A4Y5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-N7-A4Y5-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-N7-A4Y5-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-N7-A4Y5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 0; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Uterus; Histologic diagnosis: Uterine Carcinosarcoma/ MMMT: Heterologous Type; Surgical approach at diagnosis: open; Method initial path diagnosis: Tumor resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 8 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 8 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 8 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-N7-A4Y5-01A-12D-A28Q-01): tumor purity 0.93, ploidy 2.74, whole-genome doublings 1.
